Gene-level copy-number profile of tumor specimen HCM-BROD-0047-C71-86A from HCMI case HCM-BROD-0047-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 61.3 years (22,404 days).
Specimen HCM-BROD-0047-C71-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e010fb7f-ad44-4a0f-b2d1-fd12ebce2a27.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0047-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,725 have no estimate.
https://portal.gdc.cancer.gov/files/c2ef7374-ae23-49e6-9932-5f78f05b28c6

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 515; copy number 2: 3,908; copy number 3: 19,158; copy number 4: 9,969; copy number 5: 16,354; copy number 6: 4,140; copy number 7: 2,261; copy number 8: 323; copy number 9: 1,633; copy number 10: 3; copy number 11: 627; copy number 13: 4.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:84,545,131–84,800,701, 3 genes (within-gene range 0–2): HNRNPA1P72, AP000852.1, AP001825.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4,851 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:28,589,323–28,643,085, 1 gene, copy number 8 (within-gene range 5–8): TAF12.
- chr1:28,643,228–34,929,650, 155 genes, copy number 7–9 (broad region; genes not listed).
- chr1:36,080,066–36,125,222, 4 genes, copy number 7: AL138787.1, TEKT2, ADPRS, COL8A2.
- chr1:36,339,624–36,385,924, 1 gene, copy number 7: STK40.
- chr1:38,885,807–38,958,925, 4 genes, copy number 7 (within-gene range 6–7): RHBDL2, RNU6-605P, Y_RNA, EIF1P2.
- chr1:108,746,674–108,809,523, 1 gene, copy number 7 (within-gene range 6–7): STXBP3.
- chr1:108,815,898–108,963,504, 4 genes, copy number 7: AKNAD1, SPATA42, GPSM2, CLCC1.
- chr5:51,886,688–51,886,769, 1 gene, copy number 8: RNA5SP182.
- chr5:61,831,947–109,196,841, 658 genes, copy number 7–13 (within-gene range 4–13) (broad region; genes not listed).
- chr5:109,014,834–111,130,502, 27 genes, copy number 9: RNU6-47P, GJA1P1, AC116428.1, AC008467.1, PJA2, AC010625.1, AC091917.3, AC091917.2, AC091917.1, KRT18P42, MAN2A1-DT, MAN2A1, RN7SKP230, AC008417.1, LINC01848, PGAM5P1, TMEM232, MIR548F3, AC008650.1, SLC25A46, AC008782.1, BCLAF1P1, AC010395.1, AC010395.2, TSLP, AC008572.1, WDR36.
- chr5:173,888,349–173,961,980, 1 gene, copy number 8: CPEB4.
- chr7:16,646,131–159,233,377, 2,662 genes, copy number 7–11 (broad region; genes not listed).
- chr19:4,969,113–5,791,225, 18 genes, copy number 7: KDM4B, PTPRS, AC022517.1, RPL32P34, AC005790.1, ZNRF4, TINCR, SNRPEP4, SAFB2, SAFB, RPL36, MICOS13, HSD11B1L, LONP1, CATSPERD, PRR22, AC011499.1, DUS3L.
- chr19:7,018,969–30,957,192, 974 genes, copy number 7 (broad region; genes not listed).
- chr19:31,167,457–31,225,143, 1 gene, copy number 7: LINC01791.
- chr19:36,173,406–42,919,563, 335 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr22:18,846,811–18,861,049, 1 gene, copy number 7 (within-gene range 2–7): AC008132.1.
- chr22:18,906,028–18,947,732, 3 genes, copy number 10 (within-gene range 4–10): DGCR6, AC007326.4, PRODH.

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
